Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A43I, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A43I-01A (Primary Tumor).

[page 1 of 4]
PREVIOUS DIAGNOSIS INQUIRY

SEX: [REDACTED]

PAT TYPE: [REDACTED]

REQ DOC: [REDACTED]

OPER DATE: [REDACTED]

VERIFIED BY: [REDACTED]

ACCESSION: [REDACTED]

PROCEDURE: APMI

ADDENDUM REPORT FOLLOWING IMMUNOHISTOCHEMICAL STAINS ON PART #1: (

=====

Immunohistochemical stains were performed on tissue from the stomach nodule (part #1). Antibodies directed against C-kit and smooth muscle actin were used. The tumor cells stain positively for C-kit, and negatively for smooth muscle actin (background smooth muscle cells do stain). The immunohistochemical profile of supports the diagnosis of a gastrointestinal stromal tumor (GIST). Based on the size (0.4 cm), location and lack of mitotic figures, this is an incidental benign GIST

VERIFIED BY: [REDACTED]

PROCEDURE: APOX

1. Gastric nodule, excision: Benign gastrointestinal stromal tumor (0.4 cm).
- 2-9. Please see previous report for diagnoses.

[REDACTED], the signing staff pathologist, have personally examined and interpreted the slides from this case.

"This test was developed and its performance characteristics determined by the cleared or approved by the U.S. Food and Drug Administration. (The FDA has determined that such clearance is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ["CLIA"] as qualified to perform high complexity testing)."

OPER DATE: [REDACTED]

REQ DOC: [REDACTED]

ACCESSION: [REDACTED]

VERIFIED BY: [REDACTED]

PROCEDURE: SPHS

History of case: Distal esophageal mass consistent with adenocarcinoma.
Operative Procedure:

ICD-O-3
Adenocarcinoma, NOS
8140/3

Site: esophagus, distal third
C15.5

8-2012 RP

[page 2 of 4]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2

PATIENT NBR: [REDACTED]
PAT TYPE: [REDACTED]

SEX: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE: [REDACTED]

PROCEDURE: SPGD

VERIFIED BY: [REDACTED]

1. "Gastric nodule" Received fresh for frozen section in a small container is a 0.4 cm tan soft tissue bit.
Frozen section control.
2. "Distal esophagus and proximal stomach" Received in formalin in a large container is an esophagectomy specimen, consisting of: distal esophagus (9.0 cm in length), proximal stomach (4.9 cm in length) and attached perigastric adipose. There is a 2.7 x 1.7 cm, tan, polypoid mucosal mass located within the distal esophagus and involving both the GE junction and cardia. Sectioning of this area reveals a focally fibrotic, distorted and thickened wall, up to 1.7 cm. A depth of invasion cannot be determined grossly. The remaining, uninvolved esophagus, GE junction and stomach are all unremarkable. Multiple possible lymph nodes are identified up to 1.0 cm.
2A-F. Mucosal mass.
2G. Uninvolved GE junction.
2H. Six possible lymph nodes submitted whole.
2I. One possible lymph node serially sectioned.
3. "Paraesophageal lymph node" Received in formalin in a small container is a 1.1 x 0.8 x 0.5 cm lymph node with attached adipose tissue. Bisected.
4. "Paraesophageal lymph node" Received in formalin in a small container is a 1.3 x 1.1 x 0.5 cm possible lymph node. Bisected.
5. "Superior gastric margin" Received in formalin in a small container is a 1.4 x 0.7 x 0.3 cm, brown, ragged soft tissue fragment, which is partially covered by a 1.0 x 0.3 cm strip of possible mucosa. Submitted whole on edge.
6. "Left gastric lymph node" Received in formalin in a small container is a 1.5 x 1.4 x 1.0 cm lymph node with attached adipose tissue. Serially sectioned.
7. "Left lobe of thyroid" Received in formalin in a small container is a 40.0 gm, 7.3 x 6.4 x 2.1 cm, hemithyroidectomy specimen. The capsule is focally disrupted within the posterior aspect. Inked black. Upon sectioning the thyroid lobe is partially obliterated by tan, poorly circumscribed nodules occupying 80% of the parenchyma. The nodules are remarkable for scattered calcifications, hemorrhage and possible necrosis (less than 15%). No extracapsular extension is noted. The remaining, uninvolved thyroid parenchyma is red and gritty in texture.
7A. Superior pole.
7B-C. Mid pole.
7D. Inferior pole.
7E. Uninvolved thyroid parenchyma from inferior pole.
8. "Cervical-proximal margin" Received in formalin in a small container is a 0.9 cm (length) x 2.9 cm (diameter), unoriented segment of esophagus. One end is opened, while the opposite is stapled. No abnormalities are identified. Submitted whole, opened end en face. Staple line retained.
9. "Inferior gastric margin" Received in formalin in a small container is a

[page 3 of 4]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3
SEX: [REDACTED]

PAT TYPE: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE: [REDACTED]

REQ DOC: [REDACTED]

1.0 x 0.6 x 0.3 cm, brown, ragged, soft tissue fragment, which is partially surfaced by a 0.8 x 0.2 cm strip of possible mucosa. Submitted whole on edge.

FROZEN SECTION REPORT

1. Benign spindle cell lesion, favor leiomyoma. Negative for carcinoma.

I, [REDACTED], have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

PROCEDURE: SPMI

VERIFIED BY: [REDACTED]

ESOPHAGUS, GASTROESOPHAGEAL JUNCTION, INCLUDING CARDIA, CARCINOMA

LOCATION: Lower esophagus

SIZE: 2.7 cm

HAS IT BEEN TREATED PREOPERATIVE WITH CHEMO/RADIATION THERAPY?: No

TYPE OF CARCINOMA: Adenocarcinoma arising in Barrett's mucosa.

DEPTH OF INVASION: Esophageal adventitia.

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 2/10

DISTANT METASTASIS: Unknown.

RESECTION MARGIN INVOLVED: Yes. (Esophageal adventitia)

pT3 N1

PROCEDURE: SPDX

VERIFIED BY: [REDACTED]

1. Stomach, biopsy: Benign spindle cell neoplasm. Immunostains pending.
2. Distal esophagus, resection: Invasive adenocarcinoma (2.7 cm), arising in Barrett's mucosa, extending into adventitia. Tumor present at adventitial

[page 4 of 4]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 4

SEX: "

PAT TYPE:

CCESION:

OPER DATE:

REQ DOC:

margin; proximal and distal margins. Seven benign lymph nodes (0/7). See TEMPLATE.

3. Periesophageal lymph node, excision: One benign lymph node (0/1).

4. Periesophageal lymph node, excision: One lymph node, positive for metastatic adenocarcinoma (1/1).

5. Superior gastric margin, excision: Negative for malignancy.

6. Left gastric lymph node, excision: One lymph node, positive for metastatic adenocarcinoma (1/1) with extranodal extension.

7. Thyroid, left lobe, resection: Nodular hyperplasia with calcifications, negative for malignancy.

8. Esophagus, cervical/proximal margin, excision: Negative for malignancy.

9. Inferior gastric margin, excision: Negative for malignancy.

1. the signing staff pathologist, have personally examined and interpreted the slides from this case.

8/9/12

Source: NCI Genomic Data Commons file 78941b6f-8012-4f84-9e72-9069908a6cd5 (TCGA-L5-A43I.C5AF4A77-1B6D-41AE-9382-C47DF7F55646.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).